Surgical pathology report (de-identified scan), TCGA case TCGA-55-1595, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-1595-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

[REDACTED]

==== ADDENDUM REPORT #1; COMMENT: =====

Cytokeratin stain, performed on blocks B and C, are negative for metastatic carcinoma. The control slides are reviewed and found to stain appropriately. The final diagnosis remains unchanged.

[REDACTED]

==== ADDENDUM REPORT #1; DIAGNOSIS: =====
PLEASE SEE ORIGINAL DIAGNOSIS

[REDACTED]

SURGICAL PATHOLOGY REPORT

ACCESSION #: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. SUBCARINAL LYMPH NODE
- B. INFERIOR PULMONARY LIGAMENT LYMPH NODE
- C. PROXIMAL BRONCHIAL LYMPH NODE
- D. LEFT LOWER LOBE, LUNG, DPC
- E. A-P WINDOW LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Left lung mass

==== POST-OPERATIVE DIAGNOSIS: =====

Pending pathology

==== CLINICAL INFORMATION: =====

Left lung mass; status post [REDACTED] left breast carcinoma with routine neoadjuvant chemotherapy; [REDACTED] year smoking history

==== INTRAOPERATIVE CONSULTATION: =====

DPC DIAGNOSIS: "Material submitted for possible genomic study" by [REDACTED]

==== GROSS DESCRIPTION: =====

- A. The specimen consists of a chalky sessile black node, measuring 0.9 x 0.6 x 0.4 cm. The specimen is bisected and is entirely submitted in one cassette.
- B. The specimen consists of three black rubbery nodules enveloped by a small amount of adipose tissue. The nodules measure 0.2 x 0.2 x 0.1 cm, 0.6 x 0.5 x

[page 2 of 3]
Doc
Per
Res
Rep

0.3 cm and 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted in one cassette.

C. The specimen consists of three irregular black rubbery fragments of tissue, measuring 0.3 x 0.2 x 0.2 cm, 0.7 x 0.5 x 0.2 cm, and 1.0 x 0.3 x 0.1 cm. The specimen is entirely submitted in one cassette.

Received fresh is a 109 gram lobe of left lung, measuring 15.0 cm from apex to base, 13.0 cm anterior to posterior, 3.0 cm transversely. The pleural surface is pink-purple, and has been previously inked black during pathology consultation. The hilar aspect of the specimen has been inked blue and is remarkable for multiple silver-colored metallic staples. At the hilum is a portion of bronchus, measuring 1.0 x 1.0 cm. The staple line measures 4.0 cm in length. The bronchus is now shaved. The margin of the pulmonary vessels are also inked blue and are also now shaved. The pulmonary vessels and bronchus are open and reveal unremarkable yellow-tan internal surfaces that are unobstructed. The lung has been previously transected at the base of the bronchus and is remarkable for a well-demarcated ovoid tan-gray indurated mass that has overall dimensions of 2.0 x 1.0 x 0.7 cm. The mass is present 4.0 cm from the bronchial margin and pulmonary vessel margins and 1.0 cm from the closest pleural surface in the mid portion of the specimen. The remainder of the lung is sectioned and the lung parenchyma at the apex shows marked congestion. The lung parenchyma at the base is pink-tan and aerated. Additional masses are not identified nor palpated. Representative sections, including the entire remainder of the mass are submitted in nine cassettes as follows: cassette 1 - shaved pulmonary vessels and bronchial margins; cassettes 2 through 5 - remainder of mass with pleural surface in cassette 2, mass with pleural surface and base of bronchus in cassette 3, and previously sectioned portion of mass in cassette 5; cassettes 6 and 7 - blue inked staple line margin; cassette 8 - lung parenchyma from apex; cassette 9 - lung parenchyma from base.

E. The specimen consists of three black irregular rubbery fragments of tissue, each scantily covered with lobular adipose tissue. These fragments of tissue measure 0.3 x 0.3 x 0.2 cm, 0.9 x 0.3 x 0.2 cm and 2.0 x 0.9 x 0.4 cm. The specimen is entirely submitted in one cassette.

==== MICROSCOPIC DESCRIPTION: =====

A. One slide is examined. Seen are sections of a lymph node. There is no evidence of metastatic carcinoma.

B. Two slides are examined. Seen are sections of three benign lymph nodes. There is no evidence of metastatic carcinoma.

C. One slide is examined. Seen are sections of three benign lymph nodes. There is no evidence of metastatic carcinoma.

D/DPC. Nine slides are examined. Sections of the tumor show a moderate to poorly differentiated adenocarcinoma with a clear cell component. Carcinoma

[page 3 of 3]
[REDACTED]

is focally associated with a scar. Tumor does not extend to the overlying pleura. The bronchial and vascular resection margins are negative for tumor. There is no evidence of blood/lymphatic vessel invasion.
E. One slide is examined. Seen are sections of three benign lymph nodes. There is no evidence of metastatic carcinoma.

[REDACTED]

==== SPECIAL STAINS: =====

TTF-1 (thyroid transcription factor-1) stain was performed on paraffin block [REDACTED]. The neoplastic cells show strong nuclear positivity for TTF-1. This is compatible with primary lung carcinoma. The cytokeratin stain, performed on block C, shows a lymph node with no evidence of metastatic carcinoma.

[REDACTED]

==== FINAL DIAGNOSIS: =====

- A. SUBCARINAL LYMPH NODE, EXCISION: ONE BENIGN LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1)
- B. INFERIOR PULMONARY LIGAMENT LYMPH NODES, EXCISION: THREE BENIGN LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/3)
- C. PROXIMAL BRONCHIAL LYMPH NODES, EXCISION: THREE BENIGN LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/3)
- [REDACTED] LEFT LOWER LOBE OF LUNG, LOBECTOMY:
- 1. HISTOLOGIC TYPE: ADENOCARCINOMA WITH CLEAR CELL CARCINOMA COMPONENT
- 2. HISTOLOGIC GRADE: MODERATELY TO POORLY DIFFERENTIATED
- 3. EXTENT OF INVASION: pT1 (TUMOR MEASURES 2.0 CM IN MAXIMUM DIMENSION WITHOUT INVOLVEMENT OF THE OVERLYING PLEURA)
- 4. MARGINS: BRONCHIAL AND VASCULAR RESECTION MARGINS ARE NEGATIVE FOR TUMOR
- 5. BLOOD/LYMPHATIC VESSEL INVASION: ABSENT
- 6. REGIONAL LYMPH NODES: PLEASE REFER TO SPECIMENS A THROUGH C AND SPECIMEN E
- 7. DISTANT METASTASIS: NOT ASSESSED
- E. AP WINDOW LYMPH NODE, EXCISION: THREE BENIGN LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/3)

A-MALIGNANT

[REDACTED]

Source: NCI Genomic Data Commons file 834e34be-a22f-4932-8056-bc0244d2333d (TCGA-55-1595.B4EC8FA3-74B6-4656-BD2E-6FE5BA0AF7D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).